Somatic mutation profile of tumor specimen TCGA-AN-A03X-01A (aliquot TCGA-AN-A03X-01A-21W-A019-09) from TCGA case TCGA-AN-A03X, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.4 years (27,163 days).
Specimen TCGA-AN-A03X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f21bd684-c5dd-43af-b73d-7be88a537904.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A03X-10A (Blood Derived Normal), aliquot TCGA-AN-A03X-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/077896ab-be19-49b7-a3f4-8b8906e06081

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Del 1, Frame Shift Del 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 48/229 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD34A | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.515); catalogued as rs200679750, COSV60161996; called by muse, mutect2, varscan2
- ARL6IP6 | c.638A>C p.N213T | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58444196; called by muse, mutect2, varscan2
- BMP2 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs759121274, COSV66579311; called by muse, mutect2, varscan2
- CXCR1 | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV55282912; called by muse, mutect2, varscan2
- DOCK11 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as COSV99354675; called by muse, mutect2
- EGR1 | c.1000dup p.H334Pfs*13 | Frame Shift Ins (INS) | VAF 7/32 reads (22%) | catalogued as rs746692720; called by mutect2, varscan2
- FGFR2 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100337172; called by muse, mutect2
- IL13RA2 | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV54567426; called by muse, mutect2, varscan2
- JAG1 | c.1544C>T p.T515I | Missense Mutation (SNP) | VAF 564/722 reads (78%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as CD1314414, COSV54762370; called by muse, mutect2, varscan2
- MAP3K1 | c.2068A>T p.K690* | Nonsense Mutation (SNP) | VAF 67/271 reads (25%) | catalogued as COSV68127151; called by muse, mutect2, varscan2
- MOAP1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99365796; called by muse, mutect2, varscan2
- MYH8 | c.3301C>A p.Q1101K | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.744); catalogued as COSV67971865; called by muse, mutect2, varscan2
- NCKAP1 | c.1354T>A p.C452S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV100720542; called by mutect2, varscan2
- PABPC4 | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100790928; called by muse, mutect2
- PIK3CG | c.2722A>T p.N908Y | Missense Mutation (SNP) | VAF 65/390 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63253253; called by muse, mutect2, varscan2
- PPIB | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55521232; called by muse, mutect2, varscan2
- PRICKLE4 | c.123G>A p.E41= (on ENST00000359201; = p.E81= on NM_013397.6) | Splice Region (SNP) | VAF 9/35 reads (26%) | catalogued as COSV59257385; called by muse, mutect2, varscan2
- SLAIN1 | c.1406C>T p.S469F (on ENST00000466548; = p.S206F on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs775328851, COSV57389098; called by muse, mutect2, varscan2
- SLC45A3 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100901327; called by muse, mutect2
- TLCD3B | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54228119; called by muse, mutect2, varscan2
- TTC3 | c.4026G>T p.L1342F | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as rs746033406, COSV61295692; called by muse, mutect2, varscan2
- WWP1 | c.67A>T p.T23S | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV99617164; called by muse, mutect2, varscan2
- ZNF669 | c.1385G>C p.W462S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV58539266; called by muse, mutect2, varscan2
- MAP3K1 | c.3833_3834del p.R1278Kfs*5 | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | called by mutect2, pindel, varscan2
- VPS72 | c.406_456del p.S136_Q152del | In Frame Del (DEL) | VAF 30/198 reads (15%) | called by mutect2, pindel
- ZFP36L1 | c.125dup p.T43Hfs*32 | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- GATA6 | c.1308A>G p.S436= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV52527774; called by muse, mutect2, varscan2
- GRIA4 | c.447C>T p.Y149= | Silent (SNP) | VAF 56/147 reads (38%) | catalogued as rs146471234; called by muse, mutect2, varscan2
- HDAC6 | c.552C>A p.A184= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV61930519; called by muse, mutect2, varscan2
- LRRC41 | c.1974C>T p.D658= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1207596928, COSV58442329; called by muse, mutect2, varscan2
- OR52J3 | c.402C>T p.Y134= | Silent (SNP) | VAF 41/188 reads (22%) | catalogued as rs149427006, COSV66747934; called by muse, mutect2, varscan2
- UBE4B | c.1623T>C p.F541= (on ENST00000343090 / NM_001105562.3; = p.F412= on NM_006048.5) | Silent (SNP) | VAF 51/172 reads (30%) | catalogued as rs762850040, COSV53541760; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825920 C>A | 5'Flank (SNP) | VAF 210/409 reads (51%) | called by muse, mutect2, varscan2
